Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KJ, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KJ-01A (Primary Tumor).

[page 1 of 4]
Department of Pathology

Page 1 of 4

REPORT Tel:

Unit No

Clinical Consultant & Location

Sex

This Copy For:

ICD-0-3

Melanoma, epithelial & spindle cell
mixed 8770/3
Site: Choroid C69.3
9/11/14

SPECIMEN

LEFT GLOBE

CLINICAL DETAILS

Choroidal melanoma.

MACROSCOPIC DESCRIPTION

An intact left eye.

Dimensions: Axial 22mm, Horizontal 22.5mm, Vertical 21mm

Cornea: Horizontal 12mm, Vertical 12mm
Description: clear

Optic nerve
Length 12mm, Diameter 4mm

On trans-illumination, a shadow is seen, measuring 21 x 19mm, located inferomedially.

Plane of section: Diagonally

Intraocular description:

On opening, a non-pigmented choroidal tumour (dome-shaped) is seen.

Tumour size
LBD 14mm, Height 13mm

MICROSCOPY

Histologically, the enucleated eye demonstrates a normal anterior segment with an unremarkable cornea, a deep anterior chamber and open angles. The iris leaves are unremarkable. The ciliary muscles are mildly atrophic with mild hyalinisation of the ciliary processes. The lens shows mild cataractous changes.

In the posterior segment, arising at the equator, a choroidal melanoma can be seen. This is dome-shaped with a large accompanying exudative retinal detachment. The retina

Reported:

Pathologist:

Electronically Verified:

[page 2 of 4]
printed

Department of Pathology		Page 2 of 4	
HISTOPATHOLOGY REPORT Tel:			
Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]		Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

overlying the tumour is atrophic with degenerative changes. Focally, at the apex of the tumour, there is retinal invasion.

The tumour is not pigmented and consists of a mixture of cells, both epithelioid and spindle cells, with a dominance of the latter. The melanoma cells are immunoreactive for MelanA, CD117 and HSP-27 (score 3).

The number of mitoses is high, approx. 18/40 high power fields.

The microvasculature of the melanoma is not prominent, and closed loops are not present in the tissue planes evaluated. Occasional "vascular lakes" can be observed; in these tumour cells can be seen located within the lumen. The lymphocytic infiltrate within tumour is minimal. Macrophages are scattered throughout the tumour in a mild.

There is evidence of scleral invasion in the form of perivascular and intravascular infiltration of the inferomedial vortex vein.

The optic nerve is tumour free, and demonstrates mild atrophic changes. The remaining examined vortex veins are free of tumour.

DIAGNOSIS

Choroid melanoma of mixed cell type with invasion of the inferomedial vortex vein.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed

Reported:

Pathologist:

Electronically Verified:

[page 3 of 4]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED] [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]		Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

CT LOOPS

1= No closed loops

NECROSIS

No

PIGMENTATION

No

LYMPHOCYTIC INFILTRATION

No

MITOTIC FREQUENCY

18 /40 HPF

DIFFUSE MELANOMA

No

SPREAD

5= Vortex Vein

CLEARANCE

3= Uncertain

HSP-27 POSITIVITY

3= >70%

LARGE DIAMETER

12 mm

THICKNESS

4 mm

COMMENTS:

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

Reported:

Pathologist:

Electronically Verified:

[page 4 of 4]
Department of Pathology

Page 4 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	[REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

The results of the sequence analysis of the MLPA products is printed on a separate report.

In summary, sequence analysis demonstrated: normal chromosome 1, normal chromosome 3, gains in chromosome 6p, loss in chromosome 6q, loss in chromosome 8p and gains in chromosome 8.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

IIHAA Discrepancy		✓

Source: NCI Genomic Data Commons file ed7e42b1-fb69-467f-98a7-b5bf15eba676 (TCGA-VD-A8KJ.A904183E-A6F0-4EBA-94AB-DD95A8BB58F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).